Somatic mutation profile of tumor specimen TCGA-IG-A4P3-01A (aliquot TCGA-IG-A4P3-01A-11D-A27G-09) from TCGA case TCGA-IG-A4P3, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 48.9 years (17,860 days).
Specimen TCGA-IG-A4P3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5b5d201-9302-4eb3-bff8-b53b44abaf6d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IG-A4P3-10A (Blood Derived Normal), aliquot TCGA-IG-A4P3-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c8efbdf-5f97-4358-ba7c-9adf16d1c466

The open-access MAF lists 219 somatic variants for this specimen: 175 protein-altering or splice-affecting, 42 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 162, Silent 42, Nonsense Mutation 7, Splice Site 3, Frame Shift Del 2, 3'UTR 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 23/123 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PROC | c.631C>T p.R211W | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs121918143, CM880060; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TP53 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 62/229 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs17849781, CM011015, CM052927, CM120850, CX0910928, COSV52668132, COSV52679740, COSV52684662, COSV52950563; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASDH | c.2450C>T p.S817L | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1560571387; called by muse, mutect2, varscan2
- ACTRT1 | c.881T>G p.L294R | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64419585; called by muse, mutect2, varscan2
- ADAM21 | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV50806216; called by muse, mutect2, varscan2
- ADGRL3 | c.2458G>T p.G820C (on ENST00000506720 / NM_001322402.2; = p.G752C on NM_015236.6) | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV72231712; called by muse, mutect2
- AKAP1 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs189625721, COSV100532789; called by muse, mutect2, varscan2
- ARL6IP6 | c.46G>A p.G16S | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.018); catalogued as rs776807699; called by muse, mutect2, varscan2
- BDP1 | c.1135G>C p.E379Q | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV62435028; called by muse, mutect2, varscan2
- CA10 | c.818A>C p.N273T | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53343177; called by muse, mutect2, varscan2
- CALR | c.1033G>A p.E345K | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs750961102, COSV100330677; called by muse, mutect2, varscan2
- CARD18 | c.254C>T p.S85L | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.365); catalogued as COSV101596036; called by muse, mutect2
- CASP8AP2 | c.2959C>G p.H987D | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV52750003; called by muse, mutect2, varscan2
- CASP8AP2 | c.4623C>G p.F1541L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99386807; called by muse, mutect2, varscan2
- CASP8AP2 | c.5536C>G p.H1846D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV52750514; called by muse, mutect2, varscan2
- CCDC141 | c.2706G>C p.M902I | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV55373508; called by muse, mutect2, varscan2
- CCDC163 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.124); catalogued as COSV101284477; called by muse, mutect2
- CD74 | c.28C>G p.R10G | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs776339297, COSV50532121; called by mutect2, varscan2
- CDC42BPA | c.2023C>A p.P675T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs767024673, COSV62003387, COSV62003849; called by muse, mutect2, varscan2
- CES3 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs148620443, COSV57593639; called by muse, mutect2, varscan2
- CIBAR1 | c.722C>G p.S241* | Nonsense Mutation (SNP) | VAF 16/54 reads (30%) | catalogued as rs759135660; called by muse, mutect2, varscan2
- CLASP2 | c.3154G>C p.E1052Q (on ENST00000359576; = p.E1051Q on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.127); catalogued as COSV100224418; called by muse, mutect2, varscan2
- CLEC11A | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV51573596; called by muse, mutect2, varscan2
- CSMD3 | c.10288C>T p.H3430Y (on ENST00000297405 / NM_001363185.1; = p.H3261Y on NM_052900.3) | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV52106150; called by muse, mutect2, varscan2
- DDX51 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs772880022; called by muse, mutect2, varscan2
- DGKA | c.2176del p.R726Afs*9 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | catalogued as COSV59384233; called by pindel, varscan2
- DGKA | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs751686905, COSV59383998; called by muse, varscan2
- DIP2B | c.4445C>T p.S1482L | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772210044, COSV56579943; called by muse, mutect2, varscan2
- DPYS | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60908790; called by muse, varscan2
- FMO4 | c.1131C>G p.I377M | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.893); catalogued as rs776094653; called by muse, varscan2
- GASK1B | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56706533; called by muse, mutect2, varscan2
- H2AZ1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.011); catalogued as COSV56455712; called by muse, mutect2, varscan2
- HCRTR2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV100904462; called by muse, mutect2, varscan2
- HDAC4 | c.2238C>A p.F746L | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs753482334, COSV61860486, COSV61869956; called by mutect2, varscan2
- HERC2 | c.8288C>T p.S2763F | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as COSV55345813; called by muse, mutect2
- KDM2B | c.3368G>A p.R1123Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.575); catalogued as rs781826750; called by muse, mutect2, varscan2
- KPNB1 | c.1656G>T p.L552F | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV51595251; called by muse, mutect2
- LIG3 | c.963G>C p.L321F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52008246; called by muse, mutect2, varscan2
- LRRC28 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.848); catalogued as rs773574636; called by muse, mutect2
- MBD5 | c.683G>C p.G228A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV68697169; called by muse, mutect2, varscan2
- MBTPS1 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as COSV100597829; called by muse, mutect2, varscan2
- MEIS1 | c.218G>A p.R73K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs1242392477; called by muse, mutect2, varscan2
- MKRN3 | c.640G>A p.G214S | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58809435; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1802G>T p.G601V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64054503, COSV64055254; called by mutect2, varscan2
- MSR1 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.156); catalogued as rs939251648, COSV50543867; called by muse, mutect2, varscan2
- NCL | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.06); catalogued as rs375715628; called by muse, mutect2, varscan2
- OR10X1 | c.479T>A p.L160H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.087); catalogued as COSV100936728; called by muse, mutect2, varscan2
- OR13H1 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761571973, COSV58547187; called by muse, mutect2, varscan2
- OR14K1 | c.175T>A p.F59I | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV99315575; called by muse, mutect2
- OR2F2 | c.464A>C p.N155T | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.559); catalogued as COSV101283800; called by muse, mutect2, varscan2
- OR4C12 | c.739T>G p.L247V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); catalogued as COSV58859350; called by muse, mutect2, varscan2
- OR5D14 | c.602T>G p.L201R | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.756); catalogued as rs1203752020, COSV59455376; called by muse, mutect2, varscan2
- PCDHB14 | c.1156C>G p.Q386E | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.029); catalogued as COSV53388191, COSV53391539, COSV99505690; called by muse, mutect2, varscan2
- PCDHGB7 | c.1885G>C p.V629L | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.103); catalogued as rs760207269; called by mutect2, varscan2
- PKD2 | c.710-1G>T p.X237_splice | Splice Site (SNP) | VAF 3/9 reads (33%) | catalogued as COSV52939165; called by muse, mutect2
- PREPL | c.92A>G p.Y31C | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs761628820; called by muse, mutect2, varscan2
- PRKG1 | c.731T>C p.I244T | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs769855764, COSV100909178; called by muse, mutect2, varscan2
- PSMD9 | c.64G>T p.D22Y | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as rs1220224880; called by muse, mutect2
- SERPINA1 | c.762G>C p.Q254H | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs763249215, COSV63345349; called by muse, mutect2, varscan2
- SETBP1 | c.3056G>A p.R1019H | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs140544874; called by muse, mutect2, varscan2
- SLCO1B3 | c.751G>C p.D251H | Missense Mutation (SNP) | VAF 56/180 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53938416; called by muse, mutect2, varscan2
- STARD13 | c.2276A>G p.Y759C (on ENST00000336934 / NM_001243476.3; = p.Y641C on NM_052851.3) | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs553359255, COSV55229952; called by muse, mutect2, varscan2
- SUPT20HL1 | c.2284C>G p.P762A | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199953632; called by muse, mutect2, varscan2
- SYNE1 | c.10852G>A p.E3618K (on ENST00000367255 / NM_182961.4; = p.E3625K on NM_033071.3) | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs577389543; called by muse, mutect2, varscan2
- SYNRG | c.3038C>G p.S1013C | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs372539300; called by muse, mutect2, varscan2
- TG | c.7724C>G p.S2575C | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV55082336; called by muse, mutect2, varscan2
- TGFBR3 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53021892; called by mutect2, varscan2
- TMEM241 | c.730C>A p.P244T | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.083); catalogued as COSV101271696; called by muse, mutect2
- TRAPPC4 | c.363C>G p.I121M | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.916); catalogued as COSV57722133, COSV57722348; called by muse, mutect2
- TRMU | c.1237G>T p.D413Y | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as COSV51989994, COSV51991642; called by muse, mutect2, varscan2
- TTN | c.1450G>A p.D484N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | PolyPhen benign (0.053); catalogued as rs768211726, COSV59905475, COSV60105618, COSV60358917; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- ZDHHC20 | c.454A>G p.M152V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs751466481; called by muse, mutect2, varscan2
- ABCA13 | c.13046C>G p.S4349* | Nonsense Mutation (SNP) | VAF 24/90 reads (27%) | called by muse, mutect2, varscan2
- ABCC12 | c.4064C>A p.A1355E | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- ACACB | c.4405-1G>A p.X1469_splice | Splice Site (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2, varscan2
- ADGRG4 | c.3167C>T p.S1056L | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- ANXA10 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.947); called by muse, mutect2
- AP2B1 | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); called by muse, mutect2
- ASPM | c.7058G>A p.R2353K | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ATP5F1A | c.124C>A p.H42N | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP8A1 | c.2141G>T p.G714V | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by mutect2, varscan2
- B4GALT4 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- BCL9 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- BEND5 | c.1203C>G p.I401M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BEST3 | c.1990G>C p.E664Q | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- BZW1 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- C19orf18 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC7 | c.3968G>C p.G1323A | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- CCT8L2 | c.1027A>T p.R343W | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CEP290 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CHD6 | c.6478A>G p.I2160V | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLTCL1 | c.207G>C p.E69D | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- CNR1 | c.1184T>A p.I395N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- COG1 | c.1678T>C p.Y560H | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CTSL | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- DCTN4 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- DDX39A | c.381G>C p.Q127H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- DDX56 | c.58C>G p.Q20E | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DDX60L | c.837A>T p.L279F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- DGCR2 | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DICER1 | c.3521C>A p.A1174E | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.051); called by muse, mutect2
- DNAH3 | c.10847C>T p.P3616L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH8 | c.11741T>G p.L3914R | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAJC11 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- DNAJC24 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- DST | c.21770C>G p.S7257C | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DYRK4 | c.828C>G p.I276M | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- EMC1 | c.1605G>C p.M535I | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- EPHB1 | c.1432G>C p.E478Q | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FAM133A | c.462G>T p.K154N | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- FANK1 | c.541C>G p.L181V | Missense Mutation (SNP) | VAF 32/121 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FIG4 | c.2320C>T p.Q774* | Nonsense Mutation (SNP) | VAF 5/23 reads (22%) | called by muse, mutect2, varscan2
- FRMD4A | c.2190C>G p.F730L | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GABRA2 | c.1320T>G p.Y440* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | called by muse, mutect2, varscan2
- GRAMD1C | c.610G>C p.E204Q | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.274); called by muse, mutect2
- HDAC9 | c.1666G>A p.E556K | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HIVEP1 | c.2432A>T p.K811M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HLCS | c.1643C>A p.A548D | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- HNRNPUL1 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 4/55 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2
- HTT | c.5170G>T p.E1724* | Nonsense Mutation (SNP) | VAF 3/31 reads (10%) | called by muse, mutect2
- IL10RA | c.369G>T p.V123= | Splice Region (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- IZUMO1 | c.224T>C p.M75T | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.35); called by muse, mutect2
- KSR1 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- LAMB4 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- LNX2 | c.2063G>A p.S688N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- LRP6 | c.4109C>A p.A1370D | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT tolerated (0.63); PolyPhen benign (0.013); called by muse, mutect2
- LRRC41 | c.472C>G p.L158V | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.094); called by muse, mutect2
- LRRC4C | c.593A>T p.N198I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAK | c.627C>G p.I209M | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- MAP3K5 | c.1200G>A p.M400I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MKI67 | c.1252C>G p.L418V | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- MYH2 | c.4307T>C p.L1436P | Missense Mutation (SNP) | VAF 3/51 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.581); called by muse, mutect2
- MYO18A | c.5801C>A p.A1934D | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2
- NCAPG | c.112-1G>T p.X38_splice | Splice Site (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2
- NCK1 | c.445A>C p.N149H | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- NFATC3 | c.2011G>T p.A671S | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.85); PolyPhen benign (0); called by muse, mutect2
- NMS | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- PCDH15 | c.5168C>A p.P1723H | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT tolerated, low confidence (0.12); called by muse, mutect2
- PCOLCE2 | c.674G>A p.R225K | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- PDCD6IP | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 14/60 reads (23%) | called by muse, mutect2, varscan2
- PLK4 | c.2818G>C p.E940Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPN18 | c.801G>A p.M267I | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RFC1 | c.2898C>A p.H966Q (on ENST00000381897 / NM_001363496.2; = p.H965Q on NM_002913.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.266); called by muse, mutect2
- RGS20 | c.43C>T p.H15Y | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- RP1 | c.5527G>T p.A1843S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- RPL11 | c.61C>G p.L21V (on ENST00000374550 / NM_001199802.1; = p.L22V on NM_000975.5) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- SCN1A | c.1918A>C p.K640Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.505); called by muse, mutect2, varscan2
- SEMA4F | c.1221C>G p.F407L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- SKAP2 | c.1072G>C p.D358H | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- SLC4A10 | c.1325A>C p.K442T (on ENST00000446997 / NM_001354461.2; = p.K412T on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- SLC7A3 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- SMC4 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.098); called by muse, mutect2
- SMYD1 | c.1019A>C p.E340A | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- SPANXN3 | c.394G>C p.E132Q | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SSBP4 | c.964G>C p.E322Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); called by muse, varscan2
- STAC2 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.068); called by muse, varscan2
- SYNE3 | c.1249A>T p.I417F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TBCK | c.133C>A p.L45I | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TLE2 | c.1643del p.P548Qfs*130 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- TPX2 | c.1423G>C p.E475Q | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- TRAV29DV5 | c.216C>G p.F72L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- TRIM42 | c.945C>G p.F315L | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC23 | c.70C>G p.H24D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC3 | c.438C>A p.F146L | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2D3 | c.334G>C p.D112H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- USH2A | c.6916G>A p.V2306I | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP1 | c.272A>G p.Y91C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP38 | c.209G>T p.R70L | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.94); called by muse, mutect2
- WDR17 | c.1139G>C p.G380A | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- YAE1 | c.150A>G p.I50M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- ZNF106 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF107 | c.1292A>G p.K431R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- ZNF510 | c.1380T>A p.Y460* | Nonsense Mutation (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- ZNF823 | c.175G>C p.A59P (on ENST00000341191 / NM_001297610.2; = p.A15P on NM_017507.2) | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRA2 | c.2919G>A p.L973= | Silent (SNP) | VAF 9/91 reads (10%) | catalogued as rs774366183; called by muse, mutect2, varscan2
- BAIAP3 | c.1365C>G p.A455= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as rs1418879363; called by muse, mutect2, varscan2
- CMYA5 | c.12096C>T p.F4032= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1255117463; called by muse, mutect2, varscan2
- DCLK2 | c.1341G>A p.V447= | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as COSV56198900; called by muse, mutect2, varscan2
- FCGR2C | c.486C>T p.V162= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV100913113; called by muse, mutect2, varscan2
- FSTL1 | c.657C>G p.L219= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, varscan2
- GMEB2 | c.843C>G p.L281= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs970723219; called by muse, mutect2, varscan2
- GPD2 | c.1437C>G p.L479= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- INPPL1 | c.954G>T p.V318= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- IQGAP2 | c.867G>A p.L289= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as COSV57171126, COSV57184081; called by muse, mutect2, varscan2
- LAP3 | c.1161C>G p.L387= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- MAGEL2 | c.2625C>G p.S875= | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs1204239959, COSV100046235; called by muse, mutect2, varscan2
- MMP13 | c.682T>C p.L228= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as COSV52824428; called by muse, mutect2, varscan2
- MUC16 | c.11475A>T p.P3825= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as COSV101202441, COSV67474302; called by muse, mutect2
- MUC21 | c.675C>T p.A225= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs755308293; called by muse, mutect2, varscan2
- NAV3 | c.5928G>A p.L1976= (on ENST00000397909 / NM_001024383.2; = p.L1954= on NM_014903.6) | Silent (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- OPA1 | c.537G>A p.L179= | Silent (SNP) | VAF 3/40 reads (8%) | catalogued as rs1257113329; called by muse, mutect2
- OTOF | c.1905C>A p.V635= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2, varscan2
- PDE2A | c.1098C>T p.I366= | Silent (SNP) | VAF 17/114 reads (15%) | called by muse, varscan2
- PDE7A | c.108C>T p.F36= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs975215288; called by muse, mutect2, varscan2
- PHF10 | c.369G>C p.L123= | Silent (SNP) | VAF 6/24 reads (25%) | called by muse, mutect2, varscan2
- PLD5 | c.1087T>C p.L363= (on ENST00000442594; = p.L301= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as rs1416109158, COSV59165459, COSV59170478; called by muse, mutect2
- POLR2J | c.36C>G p.L12= | Silent (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- PSMB3 | c.66C>T p.I22= | Silent (SNP) | VAF 7/36 reads (19%) | called by muse, mutect2, varscan2
- ROBO1 | c.2901C>A p.I967= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1474551030; called by muse, mutect2, varscan2
- SCN3A | c.2134C>T p.L712= | Silent (SNP) | VAF 7/27 reads (26%) | called by mutect2, varscan2
- SIPA1L2 | c.2118C>T p.I706= | Silent (SNP) | VAF 43/73 reads (59%) | catalogued as rs200442380; called by muse, mutect2, varscan2
- SLC16A5 | c.924C>T p.F308= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- SLC25A36 | c.168C>G p.V56= | Silent (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- SLC7A14 | c.1161C>T p.A387= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs375259922; called by muse, varscan2
- SVIL | c.1395G>C p.V465= | Silent (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- SYNE1 | c.1590C>T p.Y530= (on ENST00000367255 / NM_182961.4; = p.Y537= on NM_033071.3) | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as rs369178017; called by muse, varscan2
- SZT2 | c.10298G>A p.*3433= (on ENST00000634258 / NM_001365999.1; = p.*3376= on NM_015284.4) | Silent (SNP) | VAF 3/26 reads (12%) | called by muse, mutect2
- TDRD5 | c.2802G>A p.L934= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs371987660; called by muse, mutect2, varscan2
- TGFBR3 | c.837C>G p.V279= | Silent (SNP) | VAF 5/32 reads (16%) | called by muse, mutect2, varscan2
- TMEM104 | c.132C>T p.V44= | Silent (SNP) | VAF 28/63 reads (44%) | called by muse, mutect2, varscan2
- TMEM30A | c.402C>T p.Y134= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs370998387, COSV100034909; called by muse, mutect2, varscan2
- TRMT9B | c.1267C>T p.L423= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, varscan2
- VPS72 | c.309C>A p.T103= | Silent (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- ZNF212 | c.642C>A p.V214= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV60024351; called by muse, mutect2, varscan2
- ZNF598 | c.417G>A p.R139= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as rs1162132625, COSV101461990; called by muse, mutect2
- ZSWIM4 | c.915C>G p.L305= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV54323319; called by muse, mutect2, varscan2
- AMFR | c.*194C>G | 3'UTR (SNP) | VAF 13/44 reads (30%) | called by muse, mutect2, varscan2
- TCF20 | c.*56G>T | 3'UTR (SNP) | VAF 7/54 reads (13%) | called by muse, mutect2, varscan2
